Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NR, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NR-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 1
SEX: F
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

-year-old with history of dysphagia, heartburn, regurg and weight loss. Adenocarcinoma of distal esophagus. Operative Procedure: Esophagectomy.

PROCEDURE:

VERIFIED BY:

1. "Thoracic esophagus." A 15 cm long segment of esophagus and 2 x 3 cm proximal stomach. The specimen is received open. Near the GE junction there is a 3.5 x 2 cm ulcerated mass with depth of invasion 1.3 cm all the way through muscularis propria and closely approximating to serosal surface. The mass occupies 70% of the lumen circumference and with marked lumen occlusion. Tumor closely approximates the distal gastric surgical margin within 0.2 cm. The remaining esophagus and stomach are grossly unremarkable. Several gross positive lymph nodes identified, up to 1 cm in greatest dimension with no obvious actual capsular extension.
- 1A-B. Tumor with deepest invasion and adjacent gastric mucosa.
- 1C-D. Tumor with deepest invasion with adjacent esophagus.
- 1E. Tumor with closest distal surgical margin after shaving the stapled mucosa.
- 1F. Shaved stapled gastric mucosa.
- 1G. Normal appearing GE junction overlying the tumor.
- 1H. Normal appearing esophagus and unremarkable gastric mucosa.
- 1I. Grossly positive lymph nodes. Sectioned.
- 1J. Two grossly positive lymph nodes. Larger bisected and inked yellow.
- 1K. Grossly unremarkable lymph nodes.
- 1L. Grossly unremarkable lymph nodes.
2. "Proximal cervical margin." A 0.5 cm long segment of unremarkable esophagus.
3. "Lesser curve lymph node." Two 0.3 to 0.5 cm lymph nodes.

ICD-3

Adenocarcinoma NOS 8140/3
Site ^{CSCF} Esophagus, distal third C15.5
path Gastroesophageal junction C16.C
9/5/17/14

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma

If adenocarcinoma, is it arising in Barrett's mucosa, gastric cardia, or GE junction: GE junction.

Depth of invasion: Adventitia

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: F
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Number of positive lymph nodes, the total number sampled is irrelevant: 7/10

Extranodal metastasis: None

Pattern of invasion: Infiltrative

Esophageal and gastric resection margins involved: No

Deep resection margin involved: No

TNM classification: T3 N1 Mx

PROCEDURE:

VERIFIED BY:

1. Esophagus and proximal stomach, resection: Adenocarcinoma arising at the GE junction with extension to perigastric and periesophageal adipose tissue. Free margins of excision. Seven of 10 lymph nodes positive for carcinoma. See template.

2. Segment of esophagus, resection: Negative for carcinoma.

3. Lymph node of lesser curvature of stomach, excision: One of two lymph nodes positive for carcinoma.

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 85e12b5c-aee8-4a32-97c3-224fdbe33daa (TCGA-L5-A8NR.38414781-8AFA-4477-A239-1E9921C4B9BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).